Somatic mutation profile of tumor specimen TARGET-10-PAPDHA-09A (aliquot TARGET-10-PAPDHA-09A-01D) from TARGET case TARGET-10-PAPDHA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (776 days).
Specimen TARGET-10-PAPDHA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2141764-27d0-4552-aad6-ff95761a4504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDHA-10A (Blood Derived Normal), aliquot TARGET-10-PAPDHA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c867226c-945d-42e6-bda8-f9af7437198e

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC117 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV50770781; called by muse, mutect2
- FLT3 | c.1780T>G p.F594V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1057520021, COSV54051445, COSV54057242, COSV54063712; called by muse, mutect2, varscan2
- TTPA | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as rs745623765; called by muse, mutect2
- ZNF786 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs866700787; called by muse, mutect2, varscan2
- APBB1 | c.1632A>T p.Q544H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DHX16 | c.1640A>T p.K547M | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA7 | c.2012A>T p.E671V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PLXNA4 | c.2978C>A p.P993H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- RNF20 | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- F2RL2 | c.738T>C p.H246= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- SLITRK6 | c.1809C>T p.D603= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as rs756433966, COSV68389714; called by muse, mutect2, varscan2
